Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7115, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7115-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN FIVE (0/5) LYMPH NODES EXAMINED.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN SIXTEEN (0/16) LYMPH NODES EXAMINED.

TCGA-EJ-7115

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 4 + 3 = 7.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 0.5 cm.
- C. THE CARCINOMA INVOLVES LESS THAN 5% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION.
- E. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE RIGHT POSTERIOR REGION CLOSE TO THE RIGHT SEMINAL VESICLE (SLIDE 3A).
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- H. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- I. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- J. EXTENSIVE HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- K. PATHOLOGIC TNM STAGE: pT3a N0 Mx.
- L. TNM HISTOLOGIC GRADE = G3-4.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 3.6
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	70.82gm
TUMOR SIZE:	Maximum dimension: 0.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	< 5% of specimen involved by invasive tumor
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	21
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G2, Moderately differentiated

Source: NCI Genomic Data Commons file 86ef79f5-e312-4a8b-885e-fa7a53c79a43 (TCGA-EJ-7115.1638AC15-F8D6-4C88-B91E-E21033AE09DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).